Gene-level copy-number profile of tumor specimen C3L-07111-04 from CPTAC case C3L-07111, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 58.8 years (21,488 days).
Specimen C3L-07111-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a7cf9e42-0c43-41d3-b304-bf5ed20bfbc6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07111-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/8941d80c-0bcc-47b8-87cf-862cbb81ca67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 550; copy number 1: 10,593; copy number 2: 40,505; copy number 3: 5,861; copy number 4: 1,367; copy number 5: 7.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,039,761–59,314,800, 2 genes (within-gene range 0–1): AC092343.1, AC008833.1.
- chr9:21,695,176–22,029,594, 10 genes (within-gene range 0–1): KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes (within-gene range 0–1): AL449423.1, CDKN2B.
- chr9:60,914,407–61,662,690, 16 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr10:87,341,685–87,357,882, 1 gene (within-gene range 0–2): LINC00863.
- chr10:122,697,709–122,699,846, 1 gene: C10orf120.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,549,435, 7 genes, copy number 5: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42.

Autosomal genes at a single copy (total copy number 1): 8,259. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
